Somatic mutation profile of tumor specimen TCGA-3C-AALI-01A (aliquot TCGA-3C-AALI-01A-11D-A41F-09) from TCGA case TCGA-3C-AALI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.8 years (18,538 days).
Specimen TCGA-3C-AALI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f41a0b2f-161f-4875-bf39-d4502a36c361.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3C-AALI-10A (Blood Derived Normal), aliquot TCGA-3C-AALI-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b203e821-6ae8-4d70-87bd-89758969f624

The open-access MAF lists 559 somatic variants for this specimen: 412 protein-altering or splice-affecting, 130 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 365, Silent 130, Nonsense Mutation 33, Intron 8, Splice Site 6, RNA 4, Splice Region 3, 3'Flank 3, Frame Shift Ins 2, 3'UTR 2, Frame Shift Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHEK2 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | catalogued as rs768384031, COSV100101473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- H3C2 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV52517971, COSV52518546; called by muse, mutect2, varscan2
- SCN5A | c.5215C>T p.R1739W (on ENST00000333535 / NM_198056.3; = p.R1738W on NM_000335.5) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199473303, CM097684, COSV61133217; ClinVar: not provided / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- A2M | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1186241883, COSV100588608; called by muse, mutect2, varscan2
- ABCA8 | c.3558G>C p.K1186N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV52201837, COSV99285489; called by muse, mutect2, varscan2
- ACAP1 | c.1557C>G p.F519L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99341604, COSV99341842; called by muse, mutect2, varscan2
- ACSM3 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs754068408, COSV56845681; called by muse, mutect2, varscan2
- ADAD1 | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99635458; called by muse, mutect2, varscan2
- ADAMTS7 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs115303425; called by muse, mutect2, varscan2
- ADAT2 | c.351G>C p.M117I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.444); catalogued as COSV52795974; called by muse, mutect2, varscan2
- ADCY8 | c.1069G>C p.V357L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99651730; called by muse, mutect2, varscan2
- ADH6 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs61755961, COSV52955791; called by muse, mutect2, varscan2
- ADNP | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100823715; called by muse, mutect2
- ADRA2C | c.1221C>G p.I407M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100342570; called by muse, varscan2
- AHCTF1 | c.6854G>C p.R2285T (on ENST00000366508; = p.R2259T on NM_015446.5) | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV100403011; called by muse, mutect2, varscan2
- AHNAK | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV99946940; called by muse, mutect2, varscan2
- AKAP12 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53571539; called by muse, mutect2
- ALPK3 | c.587T>A p.I196N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV51940894, COSV99360705; called by muse, mutect2, varscan2
- AMELX | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV100497798; called by muse, mutect2, varscan2
- ANKRD12 | c.5476C>T p.Q1826* | Nonsense Mutation (SNP) | VAF 37/57 reads (65%) | catalogued as COSV100041118; called by muse, mutect2, varscan2
- ANKRD26 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV101063129; called by muse, mutect2, varscan2
- ANKRD27 | c.1898A>T p.Q633L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100042726; called by muse, mutect2
- AOX1 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.155); catalogued as COSV101021892, COSV65982838; called by muse, mutect2
- AP3B2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as rs1486529587, COSV55607359; called by muse, mutect2, varscan2
- APMAP | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1489940112, COSV54175122, COSV99468467; called by muse, mutect2, varscan2
- APOB | c.8392G>C p.E2798Q | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as COSV51937332, COSV51941794; called by muse, mutect2, varscan2
- ARAP1 | c.1414G>C p.E472Q (on ENST00000393609 / NM_001040118.2; = p.E227Q on NM_015242.4) | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as COSV100501798; called by muse, mutect2
- ARFGEF1 | c.5458C>T p.R1820C | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51584143; called by muse, mutect2, varscan2
- ARHGAP18 | c.1889G>C p.G630A | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100936109; called by muse, mutect2, varscan2
- ARMC6 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1420255797, COSV99523006; called by muse, mutect2, varscan2
- ASMTL | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279889985, COSV101187740; called by muse, mutect2, varscan2
- ASPG | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs370504843; called by muse, mutect2, varscan2
- ATG2A | c.5116G>A p.E1706K | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs147085310; called by muse, mutect2, varscan2
- ATP10D | c.2045G>A p.S682N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs149296162; called by muse, mutect2, varscan2
- ATXN1 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99786080; called by muse, mutect2, varscan2
- BACH2 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV57584048, COSV99998937; called by muse, mutect2, varscan2
- BAZ2A | c.4711G>A p.E1571K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs573868102, COSV99465685; called by muse, mutect2
- BIVM-ERCC5 | c.4589C>T p.S1530L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.946); catalogued as COSV100863595; called by muse, mutect2, varscan2
- BLM | c.694A>T p.S232C | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV100757150; called by muse, mutect2, varscan2
- BRICD5 | c.558G>A p.M186I | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1431836679, COSV100063422; called by muse, mutect2, varscan2
- BRMS1L | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1333187829, COSV53762160; called by muse, mutect2, varscan2
- BTBD7 | c.2414G>A p.R805K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100597706; called by muse, mutect2
- BTF3 | c.215G>C p.R72T (on ENST00000380591 / NM_001037637.1; = p.R28T on NM_001207.4) | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV60063324; called by muse, mutect2, varscan2
- C1orf141 | c.897G>C p.K299N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV100924325, COSV100924365; called by muse, mutect2, varscan2
- C20orf96 | c.234G>C p.K78N (on ENST00000360321 / NM_153269.3; = p.K77N on NM_080571.1) | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV100826705, COSV64403470; called by muse, mutect2
- C2orf16 | c.2500C>A p.L834I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV100820757; called by muse, mutect2, varscan2
- CAPRIN2 | c.1673C>G p.S558C | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as COSV99195476; called by muse, mutect2, varscan2
- CBR1 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99289448; called by muse, mutect2, varscan2
- CCDC136 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373645281; called by muse, varscan2
- CCDC57 | c.678G>C p.E226D | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101051879; called by muse, mutect2, varscan2
- CCL11 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100005521; called by muse, mutect2
- CCNT1 | c.1700C>G p.S567C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV99980677; called by muse, mutect2, varscan2
- CCNT1 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.268); catalogued as COSV56065406; called by muse, mutect2, varscan2
- CDC42BPA | c.2700G>C p.L900F | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100504667; called by muse, mutect2, varscan2
- CDYL | c.1704G>T p.E568D (on ENST00000328908 / NM_001368125.1; = p.E514D on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV100189157; called by muse, mutect2, varscan2
- CEACAM1 | c.1110G>C p.E370D | Missense Mutation (SNP) | VAF 82/148 reads (55%) | SIFT tolerated (0.67); PolyPhen benign (0.05); catalogued as rs1260305085, COSV99362094, COSV99362276; called by muse, mutect2, varscan2
- CELSR1 | c.4171G>A p.E1391K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as rs73888514; called by muse, mutect2, varscan2
- CENPC | c.2401C>T p.L801F | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.957); catalogued as COSV99893800; called by muse, mutect2, varscan2
- CENPF | c.3773T>C p.I1258T | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100871659; called by muse, mutect2, varscan2
- CENPJ | c.2437C>A p.L813I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV101121500; called by muse, mutect2, varscan2
- CEP70 | c.546A>T p.L182F | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs746135756, COSV99389075; called by muse, mutect2, varscan2
- CEP72 | c.1758G>C p.Q586H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99374695; called by muse, mutect2, varscan2
- CFAP69 | c.216G>C p.K72N | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV100290018, COSV60184021; called by muse, mutect2, varscan2
- CFTR | c.3764C>G p.S1255* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | catalogued as CM920186, CM980356, COSV50044366, COSV50049297; called by muse, mutect2, varscan2
- CHAD | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV99366146; called by muse, mutect2
- CILK1 | c.1369G>C p.E457Q (on ENST00000350082 / NM_001375397.1; = p.E450Q on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as COSV100607671; called by muse, mutect2, varscan2
- CLTC | c.4393G>A p.E1465K | Missense Mutation (SNP) | VAF 34/471 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99292055; called by muse, mutect2
- CLU | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100324254; called by muse, mutect2, varscan2
- CMYA5 | c.2903G>C p.R968T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV101483996, COSV71406197; called by muse, mutect2, varscan2
- CNBD1 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 106/294 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.675); catalogued as COSV101582197; called by muse, mutect2, varscan2
- COL1A1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs1164884387, COSV99866988; called by muse, mutect2
- COL4A3 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101170225, COSV67414765; called by muse, mutect2, varscan2
- CRNKL1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99844398; called by muse, mutect2, varscan2
- CSMD3 | c.9443C>G p.S3148C (on ENST00000297405 / NM_001363185.1; = p.S2979C on NM_052900.3) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99831656, COSV99848213; called by muse, mutect2, varscan2
- CTCF | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV50486390; called by muse, mutect2, varscan2
- CTNND1 | c.2407G>A p.E803K (on ENST00000399050 / NM_001085458.2; = p.E797K on NM_001331.3) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV100650006; called by muse, mutect2, varscan2
- CXorf38 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100010313; called by muse, mutect2, varscan2
- CYGB | c.69G>C p.E23D | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.204); catalogued as COSV99506095; called by muse, mutect2, varscan2
- CYTIP | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51636591, COSV99938718; called by muse, mutect2, varscan2
- DAAM2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV99225408; called by muse, mutect2, varscan2
- DAB1 | c.1295C>G p.S432* (on ENST00000371231; = p.S399* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV64692341, COSV64692439; called by muse, mutect2, varscan2
- DACH1 | c.2149G>A p.D717N (on ENST00000619232 / NM_001366712.1; = p.D463N on NM_004392.6) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.434); catalogued as COSV100498108; called by muse, mutect2, varscan2
- DBNL | c.943G>A p.E315K (on ENST00000448521 / NM_001014436.3; = p.E316K on NM_014063.7) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV51977115; called by muse, mutect2
- DCTPP1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100073528; called by muse, mutect2, varscan2
- DDHD1 | c.100G>C p.E34Q (on ENST00000323669; = p.E265Q on NM_030637.3) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.549); catalogued as COSV100079415; called by muse, mutect2, varscan2
- DDX41 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100286522; called by muse, mutect2, varscan2
- DDX41 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.503); catalogued as COSV100286523; called by muse, mutect2, varscan2
- DHX32 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.274); catalogued as rs749109426, COSV99501565; called by muse, mutect2, varscan2
- DHX40 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99232894; called by muse, mutect2
- DIDO1 | c.4420G>C p.E1474Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs1311903127, COSV56627428, COSV99825548; called by muse, mutect2
- DISP1 | c.905G>C p.R302T | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99450683; called by muse, mutect2, varscan2
- DNAH11 | c.4095+8C>T | Splice Region (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100178774, COSV100179474; called by muse, mutect2
- DNAI2 | c.922A>T p.I308F | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.154); catalogued as COSV100209723; called by muse, mutect2, varscan2
- DNAJC14 | c.2030C>G p.S677C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV99670690; called by muse, mutect2, varscan2
- DOCK11 | c.5137del p.E1713Kfs*2 | Frame Shift Del (DEL) | VAF 29/80 reads (36%) | catalogued as COSV52236748, COSV99353301; called by mutect2, pindel, varscan2
- DPEP1 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as rs781058936, COSV99878455; called by muse, mutect2, varscan2
- DUSP19 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100700241, COSV100700299; called by muse, mutect2, varscan2
- DYNC1H1 | c.5356G>A p.E1786K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100794772; called by muse, mutect2, varscan2
- DYNC1H1 | c.13254G>C p.K4418N | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100794774; called by muse, mutect2, varscan2
- EDAR | c.293G>C p.R98P | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs144473052, CM093365, COSV51503379, COSV99303448; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV100103579; called by muse, mutect2, varscan2
- EFHC1 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754282571, COSV100931996; called by muse, mutect2, varscan2
- EGFL6 | c.1196C>G p.S399W | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV100789874, COSV100789955; called by muse, mutect2, varscan2
- EIF4A3 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.449); catalogued as COSV53921849; called by muse, mutect2, varscan2
- ELP5 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.776); catalogued as rs1237659028, COSV100020972; called by muse, mutect2, varscan2
- EML5 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); catalogued as COSV100715438; called by muse, mutect2, varscan2
- ENAM | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV101253053; called by muse, mutect2
- ENG | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as CM051037, COSV100785279; called by muse, mutect2, varscan2
- ENPP2 | c.997G>A p.D333N (on ENST00000075322 / NM_001040092.3; = p.D385N on NM_006209.5) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367097862, COSV50023444, COSV50024597; called by muse, mutect2, varscan2
- EPS15 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV100869506, COSV65542467; called by muse, mutect2, varscan2
- ERG28 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV99471228; called by muse, mutect2, varscan2
- ETNPPL | c.927G>A p.T309= | Splice Region (SNP) | VAF 18/84 reads (21%) | catalogued as rs767838850, COSV99625160; called by muse, mutect2, varscan2
- FADS1 | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.833); catalogued as COSV100650242; called by muse, mutect2
- FAM120A | c.1193C>G p.S398C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV99465162; called by mutect2, varscan2
- FAM13A | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.13); catalogued as rs1249792980, COSV52013502, COSV99983406; called by muse, mutect2, varscan2
- FAM171B | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100488483; called by muse, mutect2, varscan2
- FAM229B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as COSV100898104, COSV64087635; called by muse, mutect2, varscan2
- FAM86B1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 50/353 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.772); catalogued as COSV100392204; called by muse, mutect2, varscan2
- FAP | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1174167963, COSV51858787; called by muse, mutect2, varscan2
- FBN1 | c.7907G>A p.G2636D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100354625; called by muse, varscan2
- FBXW7 | c.529G>C p.E177Q (on ENST00000281708 / NM_001349798.2; = p.E97Q on NM_018315.5) | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV55893252, COSV55918989, COSV55933936; called by muse, mutect2, varscan2
- FGD2 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99236071; called by muse, mutect2, varscan2
- FHL5 | c.843C>A p.D281E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100459326; called by muse, mutect2, varscan2
- FLRT3 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as COSV54061310, COSV99430191; called by muse, mutect2, varscan2
- FNBP4 | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1168200673, COSV55450729, COSV99771594; called by muse, mutect2, varscan2
- FNDC11 | c.39G>A p.M13I | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100918784; called by muse, mutect2
- FNDC3A | c.3337G>A p.E1113K (on ENST00000492622 / NM_001079673.2; = p.E1057K on NM_014923.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV101256685; called by muse, mutect2, varscan2
- FOXI2 | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV59094438; called by muse, mutect2, varscan2
- FPGS | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.398); catalogued as COSV100948804; called by muse, mutect2, varscan2
- FTO | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.033); catalogued as rs577569584, COSV67111857, COSV67113039, COSV67113404; called by muse, mutect2, varscan2
- FZD2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100190360; called by muse, mutect2
- GABRB2 | c.458+1G>T p.X153_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99195922; called by mutect2, varscan2
- GALNTL5 | c.169A>T p.I57F | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101217768; called by muse, mutect2, varscan2
- GAS2 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); catalogued as COSV104376001, COSV99534972; called by muse, mutect2, varscan2
- GAS2L2 | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs781953539; called by muse, mutect2, varscan2
- GATA2 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV100351205; called by muse, mutect2
- GINS3 | c.51G>C p.E17D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV100139271; called by muse, mutect2, varscan2
- GINS4 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99394517; called by muse, mutect2, varscan2
- GON4L | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99674042; called by muse, mutect2, varscan2
- GPR143 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV101102200; called by muse, mutect2, varscan2
- GRAMD1A | c.1481C>G p.S494C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100525956, COSV100526113; called by muse, mutect2, varscan2
- GRB14 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339598957, COSV99813926; called by muse, mutect2, varscan2
- GRIK1 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.198); catalogued as rs757670301, COSV100516529; called by muse, mutect2, varscan2
- GRIN2B | c.1778G>C p.R593T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV101663003; called by muse, mutect2
- GRM3 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100862459; called by muse, mutect2, varscan2
- GTSF1L | c.424A>T p.K142* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100883921; called by muse, mutect2, varscan2
- H2BC4 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.172); catalogued as COSV58415051, COSV58416120; called by muse, mutect2, varscan2
- H2BC9 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); catalogued as COSV55099863, COSV55100002; called by muse, mutect2, varscan2
- HKDC1 | c.885G>C p.K295N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100664513; called by muse, mutect2, varscan2
- HLF | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99872078; called by muse, mutect2
- HMCN1 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99627763; called by muse, mutect2, varscan2
- HNRNPUL2 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1565159207, COSV100079537; called by muse, mutect2, varscan2
- HOXB6 | c.603G>A p.W201* | Nonsense Mutation (SNP) | VAF 59/348 reads (17%) | catalogued as rs146970548; called by muse, mutect2, varscan2
- HOXC13 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99673354; called by muse, mutect2, varscan2
- HSPBAP1 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100063353; called by muse, mutect2, varscan2
- HTR3E | c.394G>T p.D132Y (on ENST00000415389 / NM_001256613.1; = p.D147Y on NM_182589.2) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV100093948; called by muse, mutect2, varscan2
- HUWE1 | c.9365C>T p.S3122F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99471742; called by muse, mutect2, varscan2
- HYDIN | c.13680-1G>T p.X4560_splice | Splice Site (SNP) | VAF 30/134 reads (22%) | catalogued as rs1249369136, CS157442, COSV101125036; called by muse, mutect2, varscan2
- IFNGR1 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 38/56 reads (68%) | catalogued as COSV100880452; called by muse, mutect2, varscan2
- IGF1R | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99151138; called by muse, mutect2, varscan2
- IL5RA | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 72/166 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99842897; called by muse, mutect2
- ILDR1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV56550346; called by muse, mutect2, varscan2
- INPP4A | c.2548C>T p.R850C (on ENST00000074304 / NM_001134224.1; = p.R811C on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs768206909, COSV99303363; called by muse, mutect2, varscan2
- INTS6 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV60880737; called by muse, mutect2, varscan2
- IP6K3 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53389382; called by muse, mutect2, varscan2
- ITPK1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs767945252, COSV50894878, COSV50896361; called by muse, mutect2, varscan2
- KCNJ14 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.077); catalogued as COSV100655764; called by muse, mutect2
- KCNQ1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs199472704, CM057183, COSV99326491; ClinVar: not provided; called by muse, mutect2, varscan2
- KDM5B | c.1370G>A p.S457N | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV52504870; called by muse, varscan2
- KDM5B | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs777450660, COSV99350449; called by muse, mutect2, varscan2
- KDM6A | c.3288G>T p.W1096C | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100938084; called by muse, mutect2, varscan2
- KHDRBS3 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 23/162 reads (14%) | catalogued as COSV100878527; called by muse, mutect2, varscan2
- KIAA1522 | c.1982C>T p.S661F (on ENST00000373480 / NM_001198972.2; = p.S720F on NM_020888.3) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as COSV99614498; called by muse, mutect2, varscan2
- KIF11 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV99585774; called by muse, mutect2, varscan2
- KIF1A | c.2407G>C p.E803Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.579); catalogued as COSV100240104; called by muse, mutect2
- KIF26B | c.4771C>G p.R1591G | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV100832133, COSV63651465; called by muse, mutect2, varscan2
- KLHL17 | c.1204G>C p.D402H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.983); catalogued as COSV100497968, COSV100498031; called by muse, mutect2, varscan2
- KMT2C | c.4001C>G p.S1334C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100070629; called by muse, mutect2, varscan2
- KMT2E | c.3046G>C p.E1016Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.398); catalogued as COSV99996143; called by muse, mutect2, varscan2
- KRBA1 | c.2161C>G p.P721A | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV99752544; called by muse, mutect2, varscan2
- KRT79 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100398410; called by muse, mutect2, varscan2
- KSR1 | c.2430G>C p.Q810H (on ENST00000644974 / NM_001367810.1; = p.Q695H on NM_014238.2) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99259221; called by muse, mutect2, varscan2
- KSR2 | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV100194808; called by muse, mutect2, varscan2
- LCT | c.1912G>C p.D638H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as COSV51557530, COSV99929240; called by muse, mutect2, varscan2
- LONP2 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV99589069; called by muse, mutect2, varscan2
- LRATD1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs756473710, COSV54472299, COSV54473759; called by muse, mutect2, varscan2
- LRBA | c.7996C>G p.L2666V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.688); catalogued as COSV100841385; called by muse, mutect2, varscan2
- LRP2 | c.2771-1G>C p.X924_splice | Splice Site (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99787878; called by muse, mutect2, varscan2
- LRRC45 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100141785; called by muse, mutect2, varscan2
- LRRC8A | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99396481; called by muse, mutect2
- LTBP1 | c.4960G>C p.D1654H (on ENST00000404816 / NM_206943.4; = p.D1328H on NM_000627.4) | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99698125; called by muse, mutect2, varscan2
- MAGEB6B | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); catalogued as rs779810327; called by muse, mutect2, varscan2
- MAP3K10 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99454252; called by muse, mutect2, varscan2
- MAP7 | c.2064G>C p.Q688H | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100643834, COSV63421718; called by muse, mutect2, varscan2
- METTL6 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV101085024; called by muse, mutect2, varscan2
- MICALL2 | c.288G>C p.L96F | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV52516827; called by muse, mutect2
- MIER1 | c.1255G>C p.V419L (on ENST00000355356 / NM_001077701.3; = p.V436L on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100590932; called by muse, mutect2
- MME | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100852359; called by muse, mutect2, varscan2
- MNS1 | c.1127G>A p.R376K | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as COSV53068493, COSV99549515; called by muse, mutect2, varscan2
- MRFAP1 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV100307612; called by muse, mutect2, varscan2
- MRM1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.144); catalogued as rs1273431324; called by muse, mutect2
- MRPL53 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs150499635; called by muse, mutect2, varscan2
- MUC17 | c.4214C>G p.T1405S | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.855); catalogued as COSV100072793, COSV60306415; called by muse, mutect2, varscan2
- MYO10 | c.5425G>C p.E1809Q | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57029371; called by muse, mutect2
- MYO18A | c.2520C>G p.I840M | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs267604786, COSV100572158, COSV62873017; called by muse, mutect2
- MYZAP | c.1271G>C p.R424T (on ENST00000267853 / NM_001018100.5; = p.R396T on NM_152451.7) | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV99984871, COSV99985339; called by muse, mutect2, varscan2
- NAV1 | c.3223G>A p.E1075K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99818648; called by muse, mutect2, varscan2
- NAV3 | c.3628G>A p.E1210K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV99889592; called by muse, mutect2, varscan2
- NCOA6 | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as COSV100749960; called by muse, mutect2, varscan2
- NELL1 | c.2347A>C p.M783L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV100120640, COSV54238549; called by muse, mutect2, varscan2
- NEO1 | c.1015+2T>C p.X339_splice | Splice Site (SNP) | VAF 74/119 reads (62%) | catalogued as COSV56075406; called by muse, mutect2, varscan2
- NEXN | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); catalogued as COSV100331173; called by muse, mutect2, varscan2
- NFKB2 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as COSV99502984; called by muse, mutect2, varscan2
- NID1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV51628387, COSV99937393; called by muse, mutect2
- NIP7 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99650693; called by muse, mutect2
- NLN | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as rs1285483912, COSV101114222; called by muse, mutect2, varscan2
- NOSTRIN | c.1283C>A p.S428Y (on ENST00000317647 / NM_001039724.4; = p.S350Y on NM_052946.3) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV100473414; called by muse, mutect2, varscan2
- NOTCH3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs761407832, COSV54635460; called by muse, mutect2, varscan2
- NR2F1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs776020140, COSV59067477, COSV59068187; called by muse, mutect2, varscan2
- NRXN1 | c.4151G>C p.R1384T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs373723029, COSV60481978, COSV60488064; called by muse, varscan2
- NSRP1 | c.1672G>C p.D558H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55935293, COSV99898326; called by muse, mutect2, varscan2
- NT5DC3 | c.315C>A p.Y105* | Nonsense Mutation (SNP) | VAF 21/115 reads (18%) | catalogued as COSV101230928; called by muse, mutect2, varscan2
- NUDT10 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 81/333 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV100726805, COSV62853949; called by muse, varscan2
- NUFIP2 | c.1270G>C p.D424H | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV99837366; called by muse, mutect2
- NYAP2 | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV99796340; called by muse, mutect2, varscan2
- OR2L8 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100594144, COSV61726435; called by muse, mutect2, varscan2
- OR2M7 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100522508; called by muse, mutect2, varscan2
- OR2T27 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761109741, COSV100788207; called by muse, mutect2, varscan2
- OR4C46 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100060622, COSV60219242; called by muse, mutect2
- OR52B2 | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV101603939, COSV73209551; called by muse, mutect2, varscan2
- OR5D16 | c.861G>C p.L287F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101003916, COSV65721447; called by muse, mutect2
- ORC2 | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1325646299, COSV99309512; called by muse, mutect2, varscan2
- OVCH1 | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100548454; called by muse, mutect2, varscan2
- P2RX3 | c.561G>A p.E187= | Splice Region (SNP) | VAF 21/49 reads (43%) | catalogued as COSV54441853; called by muse, mutect2, varscan2
- PALB2 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as COSV99848407; called by muse, mutect2, varscan2
- PCDH15 | c.5834A>G p.E1945G | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as rs772070028, COSV100227837, COSV57342026; called by muse, mutect2, varscan2
- PCDHB1 | c.187G>C p.G63R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.17); catalogued as COSV100128137, COSV100128376; called by muse, mutect2, varscan2
- PCDHB14 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as COSV53387890, COSV99505782; called by muse, mutect2, varscan2
- PELI2 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.582); catalogued as rs749388627, COSV50709979; called by muse, mutect2, varscan2
- PHF21A | c.1907C>T p.S636F (on ENST00000418153 / NM_001101802.3; = p.S590F on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99138378; called by muse, mutect2, varscan2
- PIGQ | c.1256C>G p.S419* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV50313311, COSV99215969; called by muse, mutect2
- PIWIL1 | c.2028A>T p.K676N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV99806273; called by muse, mutect2, varscan2
- PLCL2 | c.2200A>T p.R734W (on ENST00000615277 / NM_001144382.2; = p.R608W on NM_015184.5) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101196683; called by muse, mutect2, varscan2
- PLEKHA8 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1275588712, COSV51652999; called by muse, mutect2, varscan2
- PLEKHM2 | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV65395527; called by muse, mutect2
- PLSCR3 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100247911; called by muse, mutect2, varscan2
- PMS2 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs587780051, COSV99764139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNMA2 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as COSV101580614; called by muse, mutect2, varscan2
- PNPLA6 | c.1522G>T p.A508S (on ENST00000414982 / NM_001166111.2; = p.A460S on NM_006702.5) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99653529; called by muse, mutect2, varscan2
- PNPO | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.174); catalogued as COSV99846491; called by muse, mutect2
- POLQ | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV99952089; called by muse, mutect2, varscan2
- POMGNT1 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | PolyPhen benign (0.345); catalogued as COSV100915530; called by muse, mutect2, varscan2
- PPEF2 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs748777765, COSV99714433; called by muse, varscan2
- PPFIA4 | c.1342G>C p.E448Q (on ENST00000447715; = p.E444Q on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV99690507; called by muse, mutect2, varscan2
- PPP2R3A | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1020004756, COSV53865101; called by muse, mutect2, varscan2
- PRAMEF1 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV100179645; called by muse, mutect2, varscan2
- PRG4 | c.3982C>G p.Q1328E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV100798175; called by muse, mutect2, varscan2
- PRKAA1 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.763); catalogued as COSV99713211; called by muse, mutect2, varscan2
- PRKAR1B | c.1101G>C p.K367N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV100816619; called by muse, mutect2
- PRKCE | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV60328352; called by muse, mutect2, varscan2
- PRKCSH | c.1086G>C p.Q362H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV99371473; called by muse, mutect2, varscan2
- PRKDC | c.1855G>C p.D619H | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100040015, COSV58064340; called by muse, mutect2, varscan2
- PROCR | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99405723; called by muse, mutect2, varscan2
- PRSS12 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV99628114; called by muse, mutect2, varscan2
- PRTG | c.2315A>G p.Y772C | Missense Mutation (SNP) | VAF 93/301 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101221354, COSV101221486; called by muse, mutect2, varscan2
- PRTG | c.1856C>G p.P619R | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201265974, COSV101221355; called by muse, varscan2
- PSMC5 | c.1206G>C p.K402N | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99856354; called by muse, mutect2
- PSME4 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.05); catalogued as COSV101122449; called by muse, mutect2, varscan2
- PTDSS2 | c.1230C>G p.F410L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100339119; called by muse, mutect2
- PTPDC1 | c.477G>A p.W159* (on ENST00000375360 / NM_177995.3; = p.W211* on NM_152422.4) | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99997533; called by muse, mutect2, varscan2
- PTPDC1 | c.1003G>C p.E335Q (on ENST00000375360 / NM_177995.3; = p.E387Q on NM_152422.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV104387381, COSV99997535; called by muse, mutect2, varscan2
- PTPRD | c.4606C>G p.R1536G | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100644300, COSV61956200; called by muse, mutect2
- PTPRD | c.4604T>A p.L1535* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100644304; called by muse, mutect2
- PTPRZ1 | c.2893G>A p.G965S | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs142021602, COSV101099955; called by muse, mutect2, varscan2
- PUM1 | c.2154G>C p.K718N | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV99927859; called by muse, mutect2, varscan2
- QRICH2 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.389); catalogued as COSV99429120; called by muse, mutect2, varscan2
- RAD17 | c.331G>A p.E111K (on ENST00000380774 / NM_133339.2; = p.E100K on NM_002873.1) | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV99281362; called by muse, mutect2, varscan2
- RAD51AP2 | c.359C>A p.S120* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | catalogued as COSV101208321; called by muse, mutect2, varscan2
- RALGAPA2 | c.1478G>C p.R493T | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.201); catalogued as COSV52491706, COSV99173506; called by muse, mutect2, varscan2
- RASSF2 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs999842910, COSV101040723; called by muse, mutect2, varscan2
- RBBP8NL | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99436519; called by muse, mutect2, varscan2
- REPS2 | c.1469G>C p.R490T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100381051; called by muse, mutect2, varscan2
- RNF8 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100009515; called by muse, mutect2, varscan2
- RP1 | c.81G>C p.L27F | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV99607116; called by muse, mutect2, varscan2
- RPL37A | c.4-2A>T p.X2_splice | Splice Site (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100677096; called by muse, mutect2, varscan2
- RPRD2 | c.443C>G p.T148S | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.011); catalogued as COSV100954712; called by muse, mutect2, varscan2
- RPS6KA5 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100002464; called by muse, mutect2, varscan2
- RYR1 | c.4010C>T p.S1337L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs376532452; called by muse, varscan2
- RYR2 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100769578; called by muse, mutect2, varscan2
- SAFB2 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.473); catalogued as COSV99385652; called by muse, mutect2, varscan2
- SCNN1G | c.1386G>A p.W462* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as COSV55598354; called by muse, mutect2
- SEC62 | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as COSV100427922; called by muse, mutect2, varscan2
- SEPTIN6 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV59716688; called by muse, mutect2, varscan2
- SF3A2 | c.1004G>C p.G335A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99677779; called by muse, mutect2
- SF3A3 | c.260G>C p.R87T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100885628; called by muse, mutect2, varscan2
- SHANK1 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.39); catalogued as COSV99520906; called by muse, mutect2, varscan2
- SHARPIN | c.657C>G p.I219M | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV100010344; called by muse, mutect2, varscan2
- SHROOM3 | c.2479G>C p.E827Q | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV56027616, COSV99934066; called by muse, mutect2, varscan2
- SIGLEC6 | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.246); catalogued as COSV100585304, COSV58438410; called by muse, mutect2, varscan2
- SLC17A5 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100867052; called by muse, mutect2, varscan2
- SLC22A6 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1436161825, COSV100842819; called by muse, mutect2, varscan2
- SLC22A7 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV65353388, COSV65356150; called by muse, mutect2, varscan2
- SLC25A30 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1416926874, COSV60433494; called by muse, mutect2, varscan2
- SLC26A7 | c.1515C>G p.I505M | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.399); catalogued as COSV99403130; called by muse, mutect2, varscan2
- SLC39A9 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99220311; called by muse, mutect2, varscan2
- SLC6A6 | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs776981870, COSV56124052; called by muse, mutect2, varscan2
- SMG1 | c.3791C>G p.S1264* | Nonsense Mutation (SNP) | VAF 32/712 reads (4%) | catalogued as COSV101245708; called by muse, mutect2
- SNX11 | c.200G>C p.R67T | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100821736; called by muse, mutect2
- SNX19 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs750218534, COSV56288026; called by muse, mutect2, varscan2
- SNX2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV101075615, COSV101075849; called by muse, mutect2, varscan2
- SNX24 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV99756278; called by muse, mutect2, varscan2
- SON | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99277820; called by muse, mutect2, varscan2
- SPATA1 | c.658dup p.S220Kfs*8 | Frame Shift Ins (INS) | VAF 32/118 reads (27%) | catalogued as rs762460676; called by mutect2, varscan2
- SPDYE5 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1554483405; called by muse, mutect2, varscan2
- SPEF2 | c.4683C>G p.F1561L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100288954; called by muse, mutect2
- SPG11 | c.3438C>G p.I1146M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV99968446; called by muse, mutect2, varscan2
- SPTA1 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100934750; called by muse, mutect2, varscan2
- SRCAP | c.5617C>T p.R1873* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as rs766102471, COSV52682566, COSV99349456; called by muse, mutect2, varscan2
- SRCAP | c.7970C>A p.S2657* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as COSV99349893; called by muse, mutect2, varscan2
- STAC2 | c.365G>C p.S122T | Missense Mutation (SNP) | VAF 78/511 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as COSV100336344; called by muse, mutect2, varscan2
- STARD3 | c.74C>G p.S25* | Nonsense Mutation (SNP) | VAF 16/506 reads (3%) | catalogued as COSV100302801, COSV60422399; called by muse, mutect2
- STARD7 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100474629; called by muse, mutect2, varscan2
- SUOX | c.1350G>T p.W450C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99907020; called by muse, mutect2, varscan2
- SUPT16H | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99359777; called by muse, mutect2, varscan2
- SUPT5H | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1234256902, COSV100782034; called by muse, varscan2
- SVIL | c.2392G>A p.E798K (on ENST00000355867 / NM_021738.3; = p.E372K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100881204; called by muse, mutect2, varscan2
- SYT17 | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100810684; called by muse, mutect2
- TAF6 | c.2007C>A p.N669K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV100612685; called by muse, mutect2, varscan2
- TAMM41 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99808777; called by muse, mutect2, varscan2
- TAS2R10 | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53700492, COSV99555511; called by muse, mutect2
- TBCE | c.697G>A p.D233N (on ENST00000366601; = p.D296N on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV100783031; called by muse, mutect2, varscan2
- TBP | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100027283; called by muse, mutect2, varscan2
- TCP10L | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV100291868; called by muse, mutect2, varscan2
- TEKT5 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99295997; called by muse, mutect2, varscan2
- TENM1 | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 112/223 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV64425794, COSV64433025; called by muse, mutect2, varscan2
- TET1 | c.3184G>A p.D1062N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV101018001; called by muse, mutect2, varscan2
- TET2 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV99482340; called by muse, mutect2, varscan2
- TET3 | c.4257G>C p.K1419N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.171); catalogued as COSV101327759; called by muse, varscan2
- TFR2 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99355535, COSV99355560; called by muse, mutect2, varscan2
- THSD7A | c.4703G>C p.R1568T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV101349167, COSV68472333; called by muse, mutect2, varscan2
- THSD7A | c.3706G>A p.E1236K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV101439742; called by muse, mutect2, varscan2
- TIA1 | c.920G>T p.G307V (on ENST00000433529 / NM_001351511.1; = p.G296V on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV99248587; called by muse, mutect2, varscan2
- TLK2 | c.1820G>C p.G607A (on ENST00000326270 / NM_001284333.2; = p.G585A on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100408793, COSV100409030; called by muse, mutect2
- TMEM132E | c.1419-1G>T p.X473_splice (on ENST00000321639; = p.X563_splice on NM_001304438.2) | Splice Site (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100396160; called by muse, mutect2
- TMEM190 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); catalogued as COSV99404279; called by muse, mutect2, varscan2
- TMEM202 | c.485C>G p.S162* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV58983411; called by muse, mutect2, varscan2
- TMPRSS15 | c.329G>C p.R110T | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1336581675, COSV53037779; called by muse, mutect2, varscan2
- TNFAIP1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782171000, COSV99880275; called by muse, mutect2, varscan2
- TNNT2 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV52662266; called by muse, mutect2
- TNXB | c.7435G>C p.D2479H (on ENST00000647633; = p.D2232H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100926203, COSV64487941; called by muse, mutect2, varscan2
- TOP2A | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV68502998; called by muse, mutect2, varscan2
- TOR1AIP1 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99621195; called by muse, mutect2, varscan2
- TP53 | c.548C>A p.S183* | Nonsense Mutation (SNP) | VAF 186/284 reads (65%) | catalogued as COSV52662121, COSV52858115, COSV53050787, COSV53082360; called by muse, mutect2, varscan2
- TP53I13 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV99838130; called by muse, mutect2, varscan2
- TPCN1 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV100136633; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99161010; called by muse, mutect2, varscan2
- TRAF6 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100777667; called by muse, mutect2, varscan2
- TRAV16 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs751860901; called by muse, mutect2, varscan2
- TREX1 | c.301G>A p.D101N (on ENST00000625293 / NM_033629.6; = p.D91N on NM_007248.5) | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV56496784, COSV99603978; called by muse, mutect2, varscan2
- TRIM43 | c.531G>C p.Q177H | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99719922; called by muse, mutect2, varscan2
- TRIM5 | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100000271; called by muse, mutect2, varscan2
- TRIM65 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.243); catalogued as rs140315342, COSV53932298; called by muse, mutect2, varscan2
- TRMT5 | c.830C>G p.S277* | Nonsense Mutation (SNP) | VAF 18/193 reads (9%) | catalogued as COSV99712070; called by muse, mutect2
- TRPM6 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as rs778418403, CM056712, COSV62508733; called by muse, mutect2, varscan2
- TRRAP | c.11069G>A p.R3690K (on ENST00000359863 / NM_001244580.1; = p.R3661K on NM_003496.3) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as rs1249982093, COSV100705407; called by muse, mutect2, varscan2
- TSHZ3 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs780578145, COSV99551265; called by muse, mutect2, varscan2
- TTN | c.33919G>A p.E11307K (on ENST00000591111; = p.E10380K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/82 reads (23%) | PolyPhen benign (0); catalogued as rs557526069, COSV60308894, COSV60405757; called by muse, mutect2, varscan2
- UBAC2 | c.378G>C p.L126F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.158); catalogued as COSV100854216; called by muse, mutect2, varscan2
- UBE2Z | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as COSV100711527; called by muse, mutect2
- UBIAD1 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as COSV100954844; called by muse, mutect2, varscan2
- UMODL1 | c.2270C>T p.S757L (on ENST00000408910 / NM_001004416.2; = p.S885L on NM_173568.3) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs765973844, COSV68571659; called by muse, mutect2, varscan2
- USHBP1 | c.1174G>C p.E392Q | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.193); catalogued as COSV99394159; called by muse, mutect2, varscan2
- USP6 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV100003717; called by muse, mutect2, varscan2
- UTP18 | c.1565C>G p.S522C | Missense Mutation (SNP) | VAF 23/671 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.829); catalogued as COSV99834710; called by muse, mutect2
- UTRN | c.8216G>C p.R2739T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV100838414; called by muse, mutect2, varscan2
- VPS4A | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV99651916; called by muse, mutect2, varscan2
- VWF | c.2965C>A p.Q989K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.103); catalogued as COSV99778778; called by muse, mutect2
- WDR62 | c.1791C>G p.I597M | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV99543035, COSV99543551; called by muse, mutect2
- XIRP1 | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs866461525, COSV100453551; called by muse, mutect2
- XPC | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99542229; called by muse, mutect2, varscan2
- XPOT | c.1706G>C p.R569T | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV100225467; called by muse, mutect2, varscan2
- YWHAQ | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs1183336588, COSV99431021; called by muse, mutect2, varscan2
- ZBBX | c.1642C>G p.Q548E | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs199656521, COSV100283808; called by muse, mutect2, varscan2
- ZBED4 | c.1452C>G p.I484M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99351095; called by muse, varscan2
- ZDHHC15 | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs777119134, COSV100973736; called by muse, mutect2, varscan2
- ZFHX4 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV51498082; called by muse, mutect2, varscan2
- ZGPAT | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100203154; called by muse, mutect2, varscan2
- ZMYM2 | c.3520G>C p.E1174Q | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101243661; called by muse, varscan2
- ZNF142 | c.5656G>C p.E1886Q (on ENST00000411696 / NM_001379660.1; = p.E1686Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.8); catalogued as COSV101346863, COSV101346929; called by muse, mutect2
- ZNF157 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 71/101 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100998484; called by muse, mutect2, varscan2
- ZNF219 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV100070253; called by muse, mutect2, varscan2
- ZNF22 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1395938028, COSV100026571; called by muse, mutect2
- ZNF251 | c.1342C>G p.L448V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.659); catalogued as COSV99478359; called by muse, mutect2, varscan2
- ZNF287 | c.1917G>C p.Q639H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs745336057, COSV101209372; called by muse, mutect2, varscan2
- ZNF485 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100700188; called by muse, mutect2, varscan2
- ZNF534 | c.230G>C p.R77T (on ENST00000332323 / NM_001143939.3; = p.R64T on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV56520640, COSV99989638; called by muse, mutect2, varscan2
- ZNF552 | c.791G>C p.R264T | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV101197523; called by muse, mutect2, varscan2
- ZNF566 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV101091360; called by muse, mutect2, varscan2
- ZNF568 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100451248; called by muse, mutect2, varscan2
- ZNF592 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100245626, COSV55439627; called by muse, mutect2, varscan2
- ZNF628 | c.2695G>T p.E899* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV99219954; called by muse, mutect2, varscan2
- ZNF7 | c.1361C>G p.S454* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100295812; called by muse, mutect2, varscan2
- ZNF763 | c.554C>A p.S185* (on ENST00000358987 / NM_001367172.2; = p.S188* on NM_001012753.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/118 reads (21%) | catalogued as COSV100676058, COSV100676126; called by muse, mutect2, varscan2
- ZSCAN1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV99991596; called by muse, mutect2, varscan2
- ZSWIM1 | c.195C>G p.S65R | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV99666441; called by muse, mutect2, varscan2
- ZXDC | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758081002, COSV61503421; called by muse, mutect2, varscan2
- BSND | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IGKV1D-16 | c.14T>A p.V5D | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- KIR2DL3 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2
- NANOG | c.421del p.T141Pfs*8 | Frame Shift Del (DEL) | VAF 30/146 reads (21%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.1483_1484insT p.Q495Lfs*12 | Frame Shift Ins (INS) | VAF 28/84 reads (33%) | called by mutect2, pindel*, varscan2
- TRAV12-3 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AARD | c.426A>G p.S142= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100991873; called by muse, mutect2, varscan2
- ABCC11 | c.2193G>A p.Q731= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100750696; called by muse, mutect2, varscan2
- ADCY7 | c.3132C>T p.L1044= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs766933884, COSV99575919; called by muse, mutect2, varscan2
- ADRA2C | c.1296C>G p.L432= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs774369331, COSV100342572; called by muse, varscan2
- ANKRD1 | c.918C>T p.L306= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100865359, COSV65467909; called by muse, mutect2, varscan2
- ANKRD13B | c.348C>A p.I116= | Silent (SNP) | VAF 34/416 reads (8%) | catalogued as COSV101198891; called by muse, mutect2
- APOB | c.1299G>A p.A433= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1015207876, COSV99264492; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARHGAP31 | c.1626G>A p.L542= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV99956962, COSV99957554; called by muse, mutect2, varscan2
- ASAH1 | c.6C>T p.N2= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs763514683, COSV100025654; called by muse, mutect2, varscan2
- ATG4D | c.288C>G p.L96= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV100521006; called by muse, mutect2, varscan2
- ATG4D | c.472C>T p.L158= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV100521007; called by muse, mutect2, varscan2
- ATL3 | c.1389C>T p.F463= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV60295820; called by muse, mutect2, varscan2
- BAHCC1 | c.4530G>A p.K1510= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV100311506; called by muse, mutect2, varscan2
- BTRC | c.1065G>A p.V355= (on ENST00000370187 / NM_033637.4; = p.V319= on NM_003939.5) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100927794; called by muse, mutect2, varscan2
- C20orf194 | c.252G>A p.E84= | Silent (SNP) | VAF 38/231 reads (16%) | catalogued as COSV99330605; called by muse, mutect2, varscan2
- CACNA1F | c.2649C>T p.L883= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100544665; called by muse, mutect2, varscan2
- CACNA1G | c.4368C>T p.A1456= | Silent (SNP) | VAF 43/642 reads (7%) | catalogued as rs371304245; called by muse, mutect2
- CACNB1 | c.69C>T p.F23= | Silent (SNP) | VAF 76/1176 reads (6%) | catalogued as rs1454460802, COSV99841438; called by muse, mutect2
- CAPN5 | c.1470C>T p.I490= (on ENST00000456580; = p.I450= on NM_004055.5) | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV99582027; called by muse, mutect2, varscan2
- CASD1 | c.1488T>A p.R496= | Silent (SNP) | VAF 50/133 reads (38%) | catalogued as COSV99802512; called by muse, mutect2, varscan2
- CCDC102B | c.711G>A p.T237= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs147553785; called by muse, mutect2, varscan2
- CCDC87 | c.2358C>T p.L786= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100039914; called by muse, mutect2, varscan2
- CHD3 | c.412C>T p.L138= | Silent (SNP) | VAF 50/81 reads (62%) | catalogued as COSV100391090; called by muse, mutect2, varscan2
- CHST13 | c.162G>A p.K54= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV100081110; called by muse, mutect2, varscan2
- CLEC1B | c.168C>A p.V56= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100046037; called by muse, mutect2, varscan2
- DNAH1 | c.5913C>A p.L1971= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV101325532; called by muse, mutect2, varscan2
- DNAH9 | c.465C>A p.P155= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99305385; called by muse, mutect2, varscan2
- DOT1L | c.375C>G p.L125= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV67110987; called by muse, mutect2, varscan2
- EIF1AD | c.207C>T p.L69= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100381376; called by muse, mutect2, varscan2
- EIF2B4 | c.1359C>T p.V453= (on ENST00000347454 / NM_001034116.2; = p.V452= on NM_015636.3) | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100730610; called by muse, mutect2, varscan2
- ELAC2 | c.1236C>T p.L412= | Silent (SNP) | VAF 36/68 reads (53%) | catalogued as rs1181801920, COSV100568456; called by muse, mutect2, varscan2
- EPG5 | c.6561C>T p.I2187= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV99957052; called by muse, mutect2, varscan2
- EPS8L1 | c.1422G>A p.L474= (on ENST00000201647 / NM_133180.3; = p.L347= on NM_017729.3) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs760824469, COSV99136030; called by muse, mutect2, varscan2
- ERCC2 | c.1470C>T p.L490= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs1568536018, COSV67263114; called by muse, mutect2, varscan2
- ESYT3 | c.669C>A p.V223= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV100004808; called by muse, mutect2, varscan2
- EZHIP | c.1324A>C p.R442= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100539639; called by muse, mutect2, varscan2
- FAM227B | c.1440G>A p.E480= | Silent (SNP) | VAF 31/127 reads (24%) | catalogued as COSV100174826; called by muse, varscan2
- FANCB | c.2202C>T p.L734= | Silent (SNP) | VAF 39/204 reads (19%) | catalogued as COSV100146498, COSV60759685; called by muse, mutect2, varscan2
- FLCN | c.21C>G p.L7= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99550321, COSV99550643; called by muse, mutect2, varscan2
- FUT3 | c.489C>T p.S163= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs376131737, COSV99744759; called by muse, mutect2, varscan2
- GDPD5 | c.1347G>C p.L449= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100409266; called by muse, mutect2
- GNGT2 | c.54G>A p.L18= | Silent (SNP) | VAF 9/227 reads (4%) | catalogued as COSV99865460; called by muse, mutect2
- GPM6B | c.708C>A p.V236= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV100366158; called by muse, mutect2, varscan2
- GPR179 | c.2622G>A p.K874= (on ENST00000621958; = p.K873= on NM_001004334.4) | Silent (SNP) | VAF 58/896 reads (6%) | called by muse, mutect2
- GTSF1L | c.423G>A p.Q141= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs760198409, COSV100883922; called by muse, mutect2, varscan2
- H4C3 | c.69C>G p.L23= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1345042601, COSV58089868, COSV58090565; called by muse, mutect2, varscan2
- HOOK3 | c.1452G>A p.S484= | Silent (SNP) | VAF 39/207 reads (19%) | catalogued as rs993666302, COSV100295354, COSV56885860; called by muse, mutect2, varscan2
- HS3ST3A1 | c.783C>T p.P261= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs758318211, COSV99404200; called by muse, mutect2, varscan2
- HTR4 | c.894C>G p.L298= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV100087787; called by muse, mutect2, varscan2
- IGF2R | c.1929C>A p.L643= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100807269, COSV63628930; called by muse, mutect2, varscan2
- IGKV2D-24 | c.261C>T p.F87= | Silent (SNP) | VAF 36/247 reads (15%) | called by muse, varscan2
- INPPL1 | c.2109C>T p.I703= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV99996136; called by muse, mutect2, varscan2
- IRAG1 | c.1758C>G p.L586= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV101351099; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1605G>A p.P535= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as rs375943583; called by muse, mutect2
- KDM5A | c.2229C>T p.V743= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV101238745; called by muse, mutect2, varscan2
- KIAA0100 | c.2598C>G p.L866= | Silent (SNP) | VAF 12/141 reads (9%) | catalogued as COSV101197281, COSV66495633; called by muse, mutect2
- KIAA0319 | c.879C>T p.L293= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as COSV100985485; called by muse, mutect2, varscan2
- KIAA0753 | c.2490C>A p.I830= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1009743486, COSV100810575; called by muse, mutect2, varscan2
- KLRC3 | c.150G>A p.L50= | Silent (SNP) | VAF 29/152 reads (19%) | catalogued as COSV101122903; called by muse, mutect2, varscan2
- LAMA5 | c.7167C>T p.N2389= | Silent (SNP) | VAF 27/178 reads (15%) | catalogued as COSV53357652; called by muse, mutect2, varscan2
- LARGE2 | c.1761C>T p.H587= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs192814693; called by muse, mutect2, varscan2
- LDLR | c.1902C>T p.L634= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV99369844; called by muse, mutect2, varscan2
- LDLRAD4 | c.123C>T p.N41= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100762081; called by muse, mutect2, varscan2
- LILRB2 | c.39G>C p.L13= | Silent (SNP) | VAF 43/235 reads (18%) | catalogued as COSV100079240; called by muse, mutect2, varscan2
- LONRF3 | c.2082C>G p.L694= (on ENST00000371628 / NM_001031855.3; = p.L653= on NM_024778.5) | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100504347; called by muse, mutect2, varscan2
- LRTM1 | c.372G>A p.L124= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99835987; called by muse, mutect2, varscan2
- MAML1 | c.2448G>C p.L816= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV52985214, COSV99483058; called by muse, mutect2, varscan2
- MERTK | c.1323G>A p.Q441= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV99774485; called by muse, mutect2
- MORC3 | c.969C>G p.L323= | Silent (SNP) | VAF 53/173 reads (31%) | catalogued as COSV101264899, COSV68688195; called by muse, mutect2, varscan2
- MRC1 | c.3654C>A p.I1218= | Silent (SNP) | VAF 80/274 reads (29%) | called by muse, mutect2, varscan2
- MRPL4 | c.522C>G p.L174= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV99459918; called by muse, mutect2, varscan2
- MTMR14 | c.1440G>A p.K480= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV99931244; called by muse, mutect2, varscan2
- MUC16 | c.25770G>C p.V8590= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV101199497, COSV67480661; called by muse, mutect2, varscan2
- MUC16 | c.6354G>C p.A2118= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as COSV101199498, COSV67463365; called by muse, mutect2, varscan2
- MYO1E | c.2853A>G p.P951= | Silent (SNP) | VAF 71/140 reads (51%) | catalogued as COSV99895217; called by muse, mutect2, varscan2
- NANOS3 | c.210C>T p.I70= (on ENST00000397555; = p.I89= on NM_001098622.2) | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV59248897; called by muse, mutect2, varscan2
- NBPF9 | c.213G>A p.L71= | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as COSV64995768, COSV64999400; called by muse, varscan2
- NCK1 | c.633C>T p.F211= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as rs756738301, COSV99999495; called by muse, mutect2, varscan2
- NEDD4L | c.1545C>T p.F515= (on ENST00000400345 / NM_001144967.3; = p.F495= on NM_015277.6) | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV99894464; called by muse, mutect2, varscan2
- NELFA | c.1419C>T p.F473= (on ENST00000542778; = p.F462= on NM_005663.5) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100373155, COSV56388635; called by muse, mutect2, varscan2
- NME1-NME2 | c.318G>A p.L106= (on ENST00000555572; = p.L81= on NM_001018136.3) | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as COSV99184020; called by muse, mutect2
- NMT2 | c.1188G>A p.L396= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1470009962, COSV100975519; called by muse, mutect2, varscan2
- NRXN1 | c.4179G>A p.V1393= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100640191; called by muse, varscan2
- OR1J2 | c.555C>G p.L185= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as rs145791678; called by muse, mutect2, varscan2
- OS9 | c.1638C>T p.T546= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99232718; called by muse, mutect2, varscan2
- OTUB1 | c.90C>T p.I30= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs996980060, COSV100034280; called by muse, mutect2, varscan2
- PAPPA | c.4464C>G p.L1488= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as COSV100073734; called by muse, mutect2, varscan2
- PIGU | c.936C>A p.P312= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV99466297; called by muse, mutect2, varscan2
- PLCG2 | c.1791G>A p.L597= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV100842202; called by muse, mutect2, varscan2
- PLEC | c.222C>T p.L74= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100513071; called by muse, mutect2, varscan2
- PLK1 | c.339C>T p.V113= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV100267130; called by muse, mutect2, varscan2
- POLG | c.1794C>T p.V598= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99174687; called by muse, mutect2, varscan2
- POLK | c.1764G>A p.V588= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1442418948, COSV99605826; called by muse, mutect2, varscan2
- PPM1K | c.1118G>A p.*373= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99900930; called by muse, mutect2, varscan2
- PRAM1 | c.786G>A p.P262= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs1450193244, COSV55314583; called by muse, mutect2, varscan2
- PRTG | c.255C>T p.I85= | Silent (SNP) | VAF 110/199 reads (55%) | catalogued as COSV66836830; called by muse, mutect2, varscan2
- PTGR1 | c.492C>T p.L164= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV99437163; called by muse, mutect2, varscan2
- ROCK1 | c.3747C>G p.L1249= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV101296339; called by muse, mutect2
- RTEL1 | c.3657C>T p.L1219= | Silent (SNP) | VAF 13/209 reads (6%) | catalogued as COSV99422946; called by muse, mutect2
- SCX | c.594G>A p.A198= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs1356142514; called by muse, mutect2, varscan2
- SENP1 | c.507G>A p.L169= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV50286694, COSV99136877; called by muse, mutect2, varscan2
- SENP2 | c.903G>A p.T301= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs779872233, COSV56199023; called by muse, varscan2
- SH2B1 | c.957C>G p.L319= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV100451022; called by muse, mutect2, varscan2
- SH3RF3 | c.2619C>G p.L873= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100512659; called by muse, mutect2, varscan2
- SLC15A2 | c.615G>A p.L205= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99815432; called by muse, mutect2, varscan2
- SLC17A9 | c.618G>C p.L206= | Silent (SNP) | VAF 29/305 reads (10%) | catalogued as COSV100947806; called by muse, mutect2, varscan2
- SLC22A9 | c.1458C>T p.L486= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as rs771943563, COSV54168873, COSV99654933; called by muse, mutect2, varscan2
- SLIT2 | c.724C>T p.L242= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs747148502, COSV99882976; called by muse, mutect2, varscan2
- SMG8 | c.1281C>T p.F427= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as COSV56284580; called by muse, mutect2, varscan2
- SMPD3 | c.1320C>T p.L440= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs770186333, COSV99545568; called by muse, mutect2, varscan2
- SOCS7 | c.1146C>G p.L382= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as rs778693667; called by muse, mutect2
- STARD10 | c.771G>A p.A257= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1376697037, COSV100600434; called by mutect2, varscan2
- STAT2 | c.2094C>G p.V698= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV58476590; called by muse, mutect2, varscan2
- STK35 | c.783C>T p.V261= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV55692064; called by muse, mutect2, varscan2
- SUOX | c.480G>C p.L160= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99907010; called by muse, mutect2, varscan2
- TFPT | c.154C>T p.L52= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV58085785; called by muse, mutect2, varscan2
- TMCO4 | c.753G>A p.L251= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99616365; called by muse, mutect2
- TOR1AIP1 | c.426G>A p.P142= | Silent (SNP) | VAF 30/132 reads (23%) | catalogued as rs752963545, COSV99621194; called by muse, varscan2
- TPCN1 | c.1377C>T p.L459= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs780297961, COSV100136634; called by muse, mutect2, varscan2
- TRGC2 | c.513C>T p.I171= | Silent (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2
- TRIM13 | c.336G>A p.L112= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100078305; called by muse, varscan2
- TTC21B | c.220C>T p.L74= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs1559078571, COSV99692174; called by muse, mutect2, varscan2
- TTLL7 | c.1042C>T p.L348= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1351176259, COSV53086151; called by muse, mutect2, varscan2
- ULK1 | c.2880C>T p.F960= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as COSV100416767; called by muse, mutect2, varscan2
- WDR33 | c.2725C>T p.L909= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100459878; called by muse, mutect2, varscan2
- ZBTB21 | c.1986G>A p.L662= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100177051; called by muse, mutect2, varscan2
- ZNF107 | c.2319G>A p.E773= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs1297799522, COSV61332510; called by muse, mutect2, varscan2
- ZNF169 | c.321C>G p.L107= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1162593886, COSV100566206; called by muse, mutect2, varscan2
- ZNF536 | c.465G>A p.E155= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100835083; called by muse, mutect2, varscan2
- ZNF655 | c.1047G>A p.Q349= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs757796668, COSV99402078; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288116C>G | Intron (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851625 G>C | 3'Flank (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- ASIC3 | c.*15T>A | 3'UTR (SNP) | VAF 13/92 reads (14%) | catalogued as COSV99876830; called by muse, mutect2, varscan2
- BCAT1 | c.903+1754C>A | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99678431; called by muse, mutect2, varscan2
- DDHD1 | c.319+650C>G | Intron (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100079413; called by muse, mutect2, varscan2
- LEXM | c.1185-137C>T | Intron (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100827572; called by muse, mutect2, varscan2
- LINC01565 | n.1154C>G | RNA (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- MRPL39 | c.969+1061C>G | Intron (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100220914; called by muse, mutect2, varscan2
- MUC2 | chr11:1094823 C>A | 3'Flank (SNP) | VAF 86/448 reads (19%) | called by muse, mutect2, varscan2
- NBPF25P | n.1092C>T | RNA (SNP) | VAF 60/406 reads (15%) | called by muse, mutect2, varscan2
- NR2E1 | c.25+1270G>C | Intron (SNP) | VAF 42/143 reads (29%) | catalogued as rs758318309, COSV100934461; called by muse, mutect2, varscan2
- OSCAR | c.*406C>G | 3'UTR (SNP) | VAF 28/175 reads (16%) | catalogued as COSV99499793, COSV99499919, COSV99500092; called by muse, mutect2, varscan2
- OSGIN1 | n.640C>G | RNA (SNP) | VAF 17/190 reads (9%) | catalogued as COSV100652343; called by muse, mutect2
- POM121C | chr7:75416282 C>T | 3'Flank (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- PRMT2 | c.654+2223C>T | Intron (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99388617; called by muse, mutect2, varscan2
- SSPOP | n.2512G>C | RNA (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100022382; called by muse, mutect2
- TTN | c.10361-4557C>A | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100606647; called by muse, mutect2
